Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6088, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6088-01A (Primary Tumor).

CGA-CW-6088

TISSUE DESCRIPTION:

Tissue from right kidney (3.2 x 2.5 x 1.0 cm) and right kidney
(180grams, 12 x 6 x 4.6 cm) 10.5 cm ureter, adrenal (5.5 x 3.5 x 1.3 cm), right hilar, paracaval, adrenal hilar, intraoarta caval lymph nodes

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma clear cell type, forms a 6 x 6 x 3.5 cm mass located in the inferior pole of the kidney. The tumor is confined to the kidney. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is present and unremarkable.

Kidney, right, biopsy: Grade 2 (of 4) renal cell carcinoma, clear cell type, no coagulative necrosis identified.

Lymph nodes, right hilar, paracaval, intraaorta-caval, excision: Multiple (3) right hilar, (1) right paracaval, (6) right intra-aorta caval lymph nodes are negative for tumor.

Soft tissue, right adrenal hilar region, excision: Nerve tissue and ganglion. Negative for malignancy.

Source: NCI Genomic Data Commons file 8fb9de1f-eb59-4b7e-a7ce-2c34ea67b9fd (TCGA-CW-6088.7C0B8EEB-61CA-4E83-BC9B-19E58CB36DF5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).